CCDI case PBCLLP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other endocrine glands and related structures.
https://portal.gdc.cancer.gov/cases/4409de8b-302f-4ba6-bc4f-8a3baea3645d

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Pineoblastoma: ICD-O-3 morphology code: 9362/3; Tissue or organ of origin: Pineal gland; Age at diagnosis: 4.4 years (1,614 days).

Biospecimens (3 samples)
- Sample 0DUMDQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUMDX: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUME7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
